Somatic mutation profile of cancer-model specimen HCM-CSHL-0864-C44-85B (3D Organoid, passage 2; aliquot HCM-CSHL-0864-C44-85B-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0864-C44, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Skin, NOS; Tumor grade: G2; Age at diagnosis: 77.0 years (28,135 days).
Specimen HCM-CSHL-0864-C44-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56975069-7054-4466-b706-3ec0845eac3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0864-C44-10A (Blood Derived Normal), aliquot HCM-CSHL-0864-C44-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a33f85b-d920-4df6-b145-b434c887407c

The open-access MAF lists 2,334 somatic variants for this specimen: 1,511 protein-altering or splice-affecting, 723 silent, 100 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,337, Silent 723, Nonsense Mutation 110, Intron 57, Splice Region 23, Splice Site 18, 3'UTR 16, Frame Shift Del 16, 5'UTR 9, RNA 8, 5'Flank 7, Translation Start Site 4.

Variants (750 of 2,334; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.5260C>T p.R1754* | Nonsense Mutation (SNP) | VAF 117/178 reads (66%) | catalogued as rs1565642121, COSV57607374; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.3556+1G>A p.X1186_splice | Splice Site (SNP) | VAF 138/213 reads (65%) | catalogued as rs184388696, CS004618, CS951354, COSV54435060; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 220/221 reads (100%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.264G>A p.V88= | Silent (SNP) | VAF 153/232 reads (66%) | catalogued as rs759188441, CS1212566; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP11B1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 99/299 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs193922539, CM100847, COSV52826929; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ELANE | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 258/396 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137854451, CM002598, CM097558, CM135462, COSV55049733; ClinVar: pathogenic; called by muse, mutect2
- MEN1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 135/280 reads (48%) | catalogued as rs104894266, CD013181, CM970929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 162/303 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61822860, COSV61823271; called by muse, mutect2, varscan2
- SYNE1 | c.10145+1G>A p.X3382_splice (on ENST00000367255 / NM_182961.4; = p.X3389_splice on NM_033071.3) | Splice Site (SNP) | VAF 142/199 reads (71%) | catalogued as rs1563391747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 211/512 reads (41%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 277/542 reads (51%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WAC | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 118/246 reads (48%) | catalogued as rs1564421528, COSV61566638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.269); catalogued as rs1250940574; called by muse, mutect2, varscan2
- ABCA7 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 270/440 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs769354095; called by muse, varscan2
- ABCF2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs775101547, COSV55185200; called by muse, mutect2, varscan2
- ABCG1 | c.276G>A p.W92* | Nonsense Mutation (SNP) | VAF 90/163 reads (55%) | catalogued as rs1272752933, COSV59206613; called by muse, mutect2, varscan2
- ABCG2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1305398818; called by muse, mutect2, varscan2
- ABI3BP | c.3088G>C p.E1030Q | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV52533032; called by muse, mutect2, varscan2
- ABI3BP | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52548056, COSV52549099; called by muse, mutect2, varscan2
- ABRA | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 191/309 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733802; called by muse, mutect2, varscan2
- ACBD5 | c.1138G>A p.G380R (on ENST00000375888 / NM_001352568.1; = p.G371R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/425 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777179377, COSV65519996; called by muse, mutect2, varscan2
- ACCS | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 150/261 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs367774137; called by muse, mutect2, varscan2
- ACOT9 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs146707213, COSV60537735; called by muse, mutect2, varscan2
- ACVR2B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as COSV61702734; called by muse, mutect2, varscan2
- ACVRL1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1231598304; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 175/283 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAMTS12 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 248/551 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711785; called by muse, mutect2, varscan2
- ADAMTS14 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372183319; called by muse, varscan2
- ADAMTS14 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 168/328 reads (51%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as rs758515444; called by muse, varscan2
- ADAMTS5 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1429501573; called by muse, mutect2, varscan2
- ADAMTSL2 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 648/648 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs1230048977; called by muse, varscan2
- ADCY10 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 199/296 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100897080; called by muse, mutect2, varscan2
- ADGRA1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 152/642 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs982470636, COSV66926501; called by muse, mutect2, varscan2
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 138/240 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, mutect2, varscan2
- ADGRV1 | c.13280G>A p.G4427E | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs749036604; called by muse, mutect2, varscan2
- ADH1A | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1310020525; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 268/423 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2, varscan2
- AEBP1 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 393/644 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.305); catalogued as rs988846112; called by muse, mutect2, varscan2
- AFF3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV57845289; called by muse, mutect2, varscan2
- AGPAT4 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 283/430 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs779836425; called by muse, mutect2, varscan2
- AGPS | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 101/158 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51564415; called by muse, mutect2, varscan2
- AGTPBP1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 95/590 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764878950; called by muse, mutect2, varscan2
- AHNAK | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 199/405 reads (49%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1382336139; called by muse, mutect2, varscan2
- AHNAK | c.8734C>T p.P2912S | Missense Mutation (SNP) | VAF 223/513 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369247690; called by muse, mutect2, varscan2
- AKR1C1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101080524; called by muse, mutect2, varscan2
- ALAD | c.261G>A p.K87= | Splice Region (SNP) | VAF 79/486 reads (16%) | catalogued as COSV52958835; called by muse, mutect2, varscan2
- ALDH1B1 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs750694017, COSV100890901, COSV66620133; called by muse, mutect2, varscan2
- ALPL | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 143/226 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as CD117837, COSV66376610; called by muse, mutect2, varscan2
- AMBRA1 | c.2210G>A p.R737Q (on ENST00000458649 / NM_001367468.1; = p.R647Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/297 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs758225363, COSV100093511; called by muse, mutect2, varscan2
- ANGPTL5 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs757290847, COSV99043893; called by muse, mutect2, varscan2
- ANK1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1225914262; called by muse, mutect2, varscan2
- ANKMY2 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.055); catalogued as rs1205737719; called by muse, mutect2, varscan2
- ANKRD13B | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 179/402 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs754059646; called by muse, mutect2, varscan2
- ANKRD34A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 166/566 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60161440; called by muse, mutect2, varscan2
- ANKS1A | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV64462321; called by muse, mutect2, varscan2
- ANKS1B | c.2848G>A p.D950N (on ENST00000547776 / NM_152788.4; = p.D176N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/266 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs745710683, COSV59117887; called by muse, mutect2, varscan2
- ANO2 | c.2704C>T p.R902C (on ENST00000356134 / NM_001278597.3; = p.R906C on NM_001278596.3) | Missense Mutation (SNP) | VAF 167/265 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545044632, COSV100500214; called by muse, mutect2, varscan2
- ANO8 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 260/446 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs893889451; called by muse, mutect2, varscan2
- APBB2 | c.2264C>T p.T755I (on ENST00000295974 / NM_001166050.2; = p.T756I on NM_004307.2) | Missense Mutation (SNP) | VAF 131/200 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs774509520; called by muse, mutect2, varscan2
- APCS | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV54817181; called by muse, mutect2, varscan2
- APOH | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 190/365 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as rs1055073169; called by muse, mutect2, varscan2
- APOL4 | c.337C>T p.P113S (on ENST00000352371 / NM_145660.2; = p.P110S on NM_030643.4) | Missense Mutation (SNP) | VAF 146/215 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745461165; called by mutect2, varscan2
- ARFGEF3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.214); catalogued as COSV52466487, COSV99294555; called by muse, mutect2, varscan2
- ARFGEF3 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52458685; called by muse, mutect2, varscan2
- ARMC2 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100933482, COSV64551852; called by muse, mutect2, varscan2
- ARSJ | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310436940, COSV59538058; called by muse, mutect2, varscan2
- ASPM | c.3265C>T p.H1089Y | Missense Mutation (SNP) | VAF 136/204 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54133339; called by muse, mutect2, varscan2
- ASPSCR1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 263/582 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs368957042; called by muse, mutect2, varscan2
- ATF4 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs780640405; called by muse, mutect2, varscan2
- ATOH8 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 270/691 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs755196913; called by muse, mutect2, varscan2
- ATP10D | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754586853, COSV56706682; called by muse, mutect2, varscan2
- ATP13A3 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99757402; called by muse, mutect2, varscan2
- ATXN7L1 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1273927872, COSV101182278; called by muse, mutect2, varscan2
- AXL | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 224/376 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs143593613; called by muse, mutect2, varscan2
- B4GALNT4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs779965005, COSV57322909; called by muse, mutect2, varscan2
- BAG6 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 102/506 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs776884196; called by muse, mutect2, varscan2
- BBX | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 120/217 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs200978545, COSV57886792; called by muse, mutect2, varscan2
- BCAT2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 214/329 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767653663, CM159649, COSV60273628; called by muse, varscan2
- BCL11B | c.1499C>T p.P500L (on ENST00000357195 / NM_001282237.2; = p.P429L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/512 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1460285746; called by muse, mutect2, varscan2
- BCL9L | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 298/620 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs796754241; called by muse, mutect2, varscan2
- BCR | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 184/561 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as COSV59936442; called by muse, mutect2, varscan2
- BEST3 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV58303618, COSV58306588; called by mutect2, varscan2
- BLOC1S5 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 209/458 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as COSV55243435; called by muse, mutect2, varscan2
- BMP2K | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622038; called by muse, mutect2, varscan2
- BMP2K | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58593331; called by muse, mutect2, varscan2
- BRCA1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs587782882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.5536C>T p.P1846S | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as COSV99609409; called by muse, mutect2, varscan2
- BTK | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as CM092942, COSV100437590; called by muse, mutect2, varscan2
- C10orf120 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 134/246 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs267602399, COSV61491743; called by muse, mutect2, varscan2
- C11orf24 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 266/558 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100422687; called by muse, mutect2, varscan2
- C19orf53 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 203/305 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55605858; called by muse, mutect2, varscan2
- C1QTNF9B | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 83/375 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV101158563; called by muse, mutect2, varscan2
- C2orf78 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 186/333 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs761384223, COSV68516529; called by muse, mutect2, varscan2
- C4orf3 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 159/507 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs11544530; called by muse, mutect2, varscan2
- C9orf43 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 339/566 reads (60%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55913454; called by muse, mutect2, varscan2
- CA4 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 229/508 reads (45%) | catalogued as COSV56281249; called by muse, mutect2, varscan2
- CABIN1 | c.5420G>A p.R1807Q | Missense Mutation (SNP) | VAF 300/467 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs780377579, COSV54086624; called by muse, mutect2, varscan2
- CABLES2 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1217888126, COSV54156621; called by muse, mutect2, varscan2
- CACNA1C | c.4921G>A p.G1641S | Missense Mutation (SNP) | VAF 119/183 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); catalogued as rs1215938282; called by muse, mutect2, varscan2
- CACNA1F | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 408/408 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544187; called by muse, mutect2, varscan2
- CACNA2D4 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 192/280 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as rs758961705, COSV54963773; called by muse, mutect2, varscan2
- CAMK2A | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 181/399 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62247071; called by muse, mutect2, varscan2
- CAMSAP1 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 77/569 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56725174; called by muse, mutect2, varscan2
- CAPZA3 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as COSV99855956; called by muse, mutect2, varscan2
- CARMIL3 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1448155080; called by muse, mutect2, varscan2
- CCDC114 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 126/230 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs771912701; called by muse, mutect2, varscan2
- CCDC136 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 82/311 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs750620928, COSV52797650; called by muse, mutect2, varscan2
- CCDC141 | c.2883G>A p.M961I | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV55371785; called by muse, mutect2, varscan2
- CCDC141 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV55373017; called by muse, mutect2, varscan2
- CCDC168 | c.11575C>T p.L3859F | Missense Mutation (SNP) | VAF 292/401 reads (73%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.967); catalogued as COSV59425601; called by muse, mutect2, varscan2
- CCDC171 | c.3415G>A p.D1139N | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV52641110; called by muse, mutect2, varscan2
- CCDC181 | c.1447G>A p.E483K (on ENST00000367806 / NM_001300969.1; = p.E482K on NM_021179.2) | Missense Mutation (SNP) | VAF 124/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100250480; called by muse, mutect2, varscan2
- CCDC33 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767348207, COSV51431132; called by muse, mutect2, varscan2
- CCDC40 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs878855043, COSV53904176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC6 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 130/277 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as rs374602904; called by muse, mutect2, varscan2
- CCDC70 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 228/366 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as rs867701014; called by muse, mutect2, varscan2
- CCDC73 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58799359; called by muse, mutect2, varscan2
- CCT8 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54504539; called by muse, mutect2, varscan2
- CD200R1L | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV101236669; called by muse, mutect2, varscan2
- CD44 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 159/331 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs141155638; called by muse, mutect2, varscan2
- CD96 | c.1622G>A p.R541K (on ENST00000283285 / NM_198196.3; = p.R525K on NM_005816.5) | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51913253; called by muse, mutect2, varscan2
- CDH11 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 107/352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51765459; called by muse, mutect2, varscan2
- CDHR3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as rs1477102860, COSV100488747, COSV58420724; called by muse, mutect2, varscan2
- CDIP1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 142/412 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1229193945, COSV54859635; called by muse, mutect2, varscan2
- CDSN | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 377/787 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as rs896582108, COSV99457126; called by muse, mutect2, varscan2
- CEACAM20 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as COSV57600748; called by muse, mutect2, varscan2
- CECR2 | c.1981G>A p.G661R (on ENST00000342247 / NM_001290047.2; = p.G478R on NM_001290046.1) | Missense Mutation (SNP) | VAF 178/294 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1367174836; called by muse, mutect2
- CELSR2 | c.5741G>A p.R1914Q | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs1329833232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPJ | c.3695G>A p.G1232E | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1231677593; called by muse, mutect2, varscan2
- CEP85L | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 106/169 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs750507166; called by muse, mutect2, varscan2
- CFH | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs62641696, COSV66408840; called by muse, mutect2, varscan2
- CHGB | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 179/336 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs747947199, COSV66759769; called by muse, mutect2, varscan2
- CHRNA1 | c.680G>A p.R227Q (on ENST00000261007 / NM_001039523.3; = p.R202Q on NM_000079.4) | Missense Mutation (SNP) | VAF 130/365 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as rs769337073; ClinVar: uncertain significance; called by muse, varscan2
- CHRNB3 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900331287, COSV99251521; called by muse, mutect2, varscan2
- CIDEA | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs750897293; called by muse, mutect2, varscan2
- CIT | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.28); catalogued as rs1270618886, COSV55865594; called by muse, mutect2, varscan2
- CLCA4 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV65283411; called by muse, mutect2, varscan2
- CLEC18B | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 76/504 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244361176, COSV60578067; called by muse, mutect2, varscan2
- CLIP2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554729296; called by muse, mutect2, varscan2
- CMYA5 | c.5602T>G p.S1868A | Missense Mutation (SNP) | VAF 164/341 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV71408452; called by muse, mutect2, varscan2
- CNKSR2 | c.2860C>T p.R954W | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65331338; called by muse, mutect2, varscan2
- CNOT6 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs772817399, COSV99993847; called by muse, mutect2, varscan2
- CNTNAP5 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868412409, COSV70487087; called by muse, mutect2, varscan2
- CNTRL | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 131/423 reads (31%) | catalogued as COSV53044435; called by muse, mutect2, varscan2
- COL10A1 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs762721417; called by muse, mutect2, varscan2
- COL11A1 | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV100617896; called by muse, mutect2, varscan2
- COL11A2 | c.3676G>A p.E1226K (on ENST00000341947 / NM_080680.3; = p.E1119K on NM_080679.2) | Missense Mutation (SNP) | VAF 216/483 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as rs1259912377; called by muse, mutect2, varscan2
- COL15A1 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 79/610 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs778855239; called by muse, mutect2, varscan2
- COL24A1 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV65310979; called by muse, mutect2, varscan2
- COL3A1 | c.3256G>A p.G1086S | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM115013, COSV100483475; called by muse, mutect2, varscan2
- COL4A1 | c.3271G>A p.G1091R | Missense Mutation (SNP) | VAF 544/801 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011290; called by muse, mutect2, varscan2
- COL4A2 | c.3059C>T p.S1020L | Missense Mutation (SNP) | VAF 203/712 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1284408840, COSV64633252; called by muse, mutect2, varscan2
- COL4A4 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs758174051, COSV104395172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC12 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1317203075; called by muse, mutect2, varscan2
- COLGALT1 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138362382; called by muse, mutect2, varscan2
- CORO7 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 199/283 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1421700421, COSV99227634; called by muse, mutect2, varscan2
- CPA3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.975); catalogued as COSV99936069; called by muse, mutect2, varscan2
- CPNE3 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs781021543, COSV52211311; called by muse, mutect2, varscan2
- CPSF1 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 172/262 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV58235898; called by muse, mutect2, varscan2
- CPT1B | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs1489131018; called by muse, mutect2, varscan2
- CR2 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 110/181 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV65507551, COSV65508177; called by muse, mutect2, varscan2
- CRAT | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 89/723 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV58875729; called by muse, mutect2, varscan2
- CREB5 | c.173A>C p.Q58P (on ENST00000357727 / NM_182898.4; = p.Q51P on NM_004904.3) | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1263624985; called by muse, mutect2, varscan2
- CRPPA | c.845C>T p.S282F (on ENST00000407010 / NM_001368197.1; = p.S232F on NM_001101417.4) | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1187330759, COSV67907310; called by muse, mutect2, varscan2
- CRYBG3 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as rs1267016814; called by muse, mutect2, varscan2
- CSF1R | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 108/233 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM1510267, COSV53840811; called by muse, mutect2, varscan2
- CSMD3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 143/230 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52332654; called by muse, mutect2, varscan2
- CSRNP3 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV58787743; called by muse, mutect2, varscan2
- CTTNBP2 | c.1757C>A p.S586* | Nonsense Mutation (SNP) | VAF 132/410 reads (32%) | catalogued as COSV50393049; called by muse, mutect2, varscan2
- CYP1B1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 324/487 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs1212671287; called by muse, mutect2, varscan2
- DAB2IP | c.229G>A p.G77S (on ENST00000408936; = p.G49S on NM_032552.3) | Missense Mutation (SNP) | VAF 270/448 reads (60%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as rs747666068; called by muse, varscan2
- DAND5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 133/208 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs373817477; called by muse, mutect2, varscan2
- DCTN1 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs368350710; called by muse, mutect2, varscan2
- DDAH2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 320/675 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs1275918216; called by muse, mutect2, varscan2
- DDX31 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 182/1079 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.364); catalogued as rs866139523, COSV60135982; called by muse, mutect2, varscan2
- DDX4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV61756203; called by muse, mutect2, varscan2
- DDX42 | c.1026C>T p.I342= | Splice Region (SNP) | VAF 55/115 reads (48%) | catalogued as COSV63790158; called by muse, mutect2, varscan2
- DDX47 | c.562-1G>T p.X188_splice | Splice Site (SNP) | VAF 50/191 reads (26%) | catalogued as COSV61911976; called by muse, mutect2, varscan2
- DDX60 | c.4805G>A p.R1602Q | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766262357, COSV104429360; called by muse, mutect2, varscan2
- DEFB105A | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759905858; called by muse, mutect2, varscan2
- DENND1C | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 225/377 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs371338380; called by muse, mutect2, varscan2
- DGKG | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 195/451 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as rs1017655307; called by muse, mutect2, varscan2
- DISP3 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 23/633 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV53825842; called by muse, mutect2
- DLC1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs758859229; called by muse, mutect2, varscan2
- DLG4 | c.526G>A p.G176R (on ENST00000399506 / NM_001321075.3; = p.G219R on NM_001365.4) | Missense Mutation (SNP) | VAF 186/355 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758066384; called by muse, mutect2, varscan2
- DNAH10 | c.9589G>C p.E3197Q (on ENST00000409039; = p.E3136Q on NM_207437.3) | Missense Mutation (SNP) | VAF 143/591 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV68999630; called by muse, mutect2, varscan2
- DNAJC15 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs773788954; called by muse, mutect2, varscan2
- DNAJC6 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 91/158 reads (58%) | catalogued as COSV99057875; called by muse, mutect2, varscan2
- DPP10 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.439); catalogued as COSV59733683; called by muse, mutect2, varscan2
- DSCAML1 | c.4864G>A p.E1622K (on ENST00000321322; = p.E1562K on NM_020693.4) | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as COSV58400161; called by muse, mutect2, varscan2
- DUSP12 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 77/257 reads (30%) | catalogued as rs770024507; called by muse, mutect2, varscan2
- DVL3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs774816506; called by muse, varscan2
- EBF3 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100799098, COSV62479505; called by muse, mutect2, varscan2
- EGLN3 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51654198; called by muse, mutect2, varscan2
- EHBP1L1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 155/307 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as rs1189886529; called by muse, mutect2, varscan2
- EIF2B2 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 131/235 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56720212; called by muse, mutect2, varscan2
- ENPEP | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765435416; called by muse, varscan2
- EPC1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53926079, COSV99552486; called by muse, mutect2, varscan2
- EPHA5 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56634625; called by muse, mutect2, varscan2
- ERAS | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 322/324 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1557033094; called by muse, mutect2, varscan2
- ERBIN | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs1393633731; called by muse, mutect2, varscan2
- ERCC3 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs777749462; called by muse, mutect2, varscan2
- ERP27 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99844322; called by muse, mutect2, varscan2
- EVA1B | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 103/302 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54633908; called by muse, mutect2, varscan2
- EVPL | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 351/717 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs949204383; called by muse, mutect2, varscan2
- EVX1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 486/1130 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs764927169; called by muse, mutect2, varscan2
- EXTL3 | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769238546; called by muse, mutect2, varscan2
- FAM114A1 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); catalogued as rs1443169537; called by muse, mutect2, varscan2
- FAM114A2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV100491702; called by muse, mutect2, varscan2
- FAM124A | c.1256G>T p.R419L (on ENST00000322475 / NM_001242312.2; = p.R455L on NM_145019.4) | Missense Mutation (SNP) | VAF 131/397 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV54479662; called by muse, mutect2, varscan2
- FAM135B | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 207/331 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV52742375, COSV52757399; called by muse, mutect2, varscan2
- FAM13B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs150652906; called by muse, mutect2, varscan2
- FAM187B | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 178/510 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1568432177; called by muse, mutect2
- FAM71F1 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 91/297 reads (31%) | catalogued as COSV59375188; called by muse, mutect2, varscan2
- FAM89A | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs754401221; called by muse, mutect2, varscan2
- FANCI | c.3277G>A p.E1093K (on ENST00000310775 / NM_001376911.1; = p.E1033K on NM_018193.3) | Missense Mutation (SNP) | VAF 122/238 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs758575911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAS | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV58240172; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 195/196 reads (99%) | catalogued as rs547340067, COSV71672032; called by muse, varscan2
- FAT3 | c.13420G>A p.V4474M | Missense Mutation (SNP) | VAF 81/364 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs1157297135, COSV53171325; called by muse, mutect2, varscan2
- FAT3 | c.13541C>T p.S4514F | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53103331; called by muse, mutect2, varscan2
- FBP1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 177/617 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199458282; called by muse, mutect2, varscan2
- FBXL7 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 302/496 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs189208873; called by muse, mutect2, varscan2
- FER1L6 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 240/396 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV67550220; called by muse, mutect2
- FGB | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1560816739, COSV57417983; called by muse, mutect2, varscan2
- FGD3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 548/852 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV61600006; called by muse, mutect2, varscan2
- FKTN | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 192/586 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776820422, COSV99795652; called by muse, mutect2, varscan2
- FLG | c.11705C>T p.P3902L | Missense Mutation (SNP) | VAF 189/285 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV64238219, COSV64238823; called by muse, mutect2, varscan2
- FLG | c.6224C>T p.S2075F | Missense Mutation (SNP) | VAF 230/504 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1376959965; called by muse, mutect2, varscan2
- FLNA | c.4142G>A p.R1381K | Missense Mutation (SNP) | VAF 280/281 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.241); catalogued as COSV61040975; called by muse, mutect2, varscan2
- FLNA | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV61037998; called by muse, varscan2
- FMO5 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907429343; called by muse, mutect2, varscan2
- FMO5 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1165757897, COSV99567291; called by muse, mutect2, varscan2
- FNBP4 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs768346504, COSV55451906, COSV99771337, COSV99771900; called by muse, mutect2, varscan2
- FNDC3A | c.1733C>T p.S578L (on ENST00000492622 / NM_001079673.2; = p.S522L on NM_014923.5) | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV68135560; called by muse, mutect2, varscan2
- FNDC7 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54753412; called by muse, mutect2, varscan2
- FOXN1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 354/712 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs772876092; called by muse, mutect2, varscan2
- FOXS1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 277/598 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs748308318; called by muse, mutect2, varscan2
- FRMD4A | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 191/381 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs781661600; called by muse, mutect2, varscan2
- FSD2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58013464; called by muse, mutect2, varscan2
- FSIP2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); catalogued as rs986211529; called by muse, mutect2, varscan2
- FZD2 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 213/476 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100190671; called by muse, mutect2, varscan2
- GALNTL6 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72491829; called by muse, mutect2, varscan2
- GANAB | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1294139471, COSV60467946; called by muse, varscan2
- GAREM2 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 312/522 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.441); catalogued as rs1313938649; called by muse, mutect2, varscan2
- GNA12 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 264/604 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as rs375880168; called by muse, mutect2, varscan2
- GPR156 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 138/552 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs768056878, COSV59938182; called by muse, mutect2, varscan2
- GRIP1 | c.1256C>T p.S419F (on ENST00000359742 / NM_001379345.1; = p.S367F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV54033721; called by muse, mutect2, varscan2
- GRK2 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 191/386 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs773040164; called by muse, mutect2, varscan2
- GRK7 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 77/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753960342, COSV53824167; called by muse, mutect2, varscan2
- GRXCR1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 149/224 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs1262455747, COSV67674177; called by muse, mutect2, varscan2
- GSG1L2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 105/404 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1327039756; called by muse, mutect2, varscan2
- GUCY2D | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 352/633 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV54696253; called by muse, mutect2, varscan2
- H4C12 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV62743792; called by muse, mutect2, varscan2
- HABP4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 284/457 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1485989089; called by muse, mutect2, varscan2
- HBS1L | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 105/165 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV63201860; called by muse, mutect2, varscan2
- HCFC2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV57558433; called by muse, mutect2, varscan2
- HEATR1 | c.5723C>T p.S1908F | Missense Mutation (SNP) | VAF 150/247 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857708; called by muse, mutect2, varscan2
- HELZ | c.5636C>T p.A1879V | Missense Mutation (SNP) | VAF 177/400 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as rs1474954776, COSV62381207; called by muse, mutect2, varscan2
- HELZ | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs1463960097; called by muse, mutect2, varscan2
- HHIP | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV56836517; called by muse, mutect2, varscan2
- HIF3A | c.914G>A p.R305H (on ENST00000377670 / NM_152795.4; = p.R236H on NM_022462.4) | Missense Mutation (SNP) | VAF 121/459 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777671557; called by muse, mutect2, varscan2
- HINFP | c.867T>G p.C289W | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1355454265; called by muse, mutect2, varscan2
- HK1 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 251/498 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100067498; called by muse, varscan2
- HMCN1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.401); catalogued as COSV54931928; called by muse, mutect2, varscan2
- HMCN2 | c.13064G>A p.G4355E | Missense Mutation (SNP) | VAF 152/951 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1411553747; called by muse, mutect2, varscan2
- HMGA1 | c.219G>A p.R73= (on ENST00000311487 / NM_001319082.2; = p.R62= on NM_002131.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 123/258 reads (48%) | catalogued as COSV58988581; called by muse, mutect2, varscan2
- HP1BP3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100391734; called by muse, mutect2, varscan2
- HPS6 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 114/535 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as rs375236824; called by muse, mutect2, varscan2
- HRAS | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 291/545 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1309567083; called by muse, mutect2, varscan2
- HRH2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 192/437 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1265732951; called by muse, mutect2, varscan2
- HROB | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 208/474 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs748023037; called by muse, mutect2, varscan2
- HSPG2 | c.10075G>A p.D3359N | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs749843838; called by muse, mutect2, varscan2
- IER5 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 158/468 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100849695; called by muse, mutect2, varscan2
- IFI16 | c.1937C>T p.P646L (on ENST00000295809 / NM_001364867.2; = p.P590L on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 183/279 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV55534658; called by muse, mutect2, varscan2
- IGHV1-69 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs575656143; called by muse, mutect2, varscan2
- IGSF6 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs1210455639; called by muse, mutect2, varscan2
- IL17A | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 172/395 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1208310869, COSV60684303; called by muse, mutect2, varscan2
- INHBA | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 108/672 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.142); catalogued as rs1355421314, COSV54225763; called by muse, varscan2
- INPP4A | c.242C>G p.T81R | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766419021, COSV50784947; called by muse, mutect2, varscan2
- INPP4B | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV53752097; called by muse, mutect2, varscan2
- INTS13 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 153/231 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99677492; called by muse, mutect2, varscan2
- INTS6 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 152/270 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV60879557, COSV60881565; called by muse, mutect2, varscan2
- INTS6 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 154/270 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV60879562; called by muse, mutect2, varscan2
- IQCM | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs762567052; called by muse, mutect2, varscan2
- ITGAD | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1384228307; called by muse, mutect2, varscan2
- ITIH5 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV53659948; called by muse, mutect2, varscan2
- ITPR2 | c.7549C>T p.R2517* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs753439959, COSV67274830; called by muse, mutect2, varscan2
- ITPR3 | c.7627C>T p.L2543= | Splice Region (SNP) | VAF 35/185 reads (19%) | catalogued as rs748802344; called by muse, mutect2, varscan2
- ITSN2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 133/225 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs138489908; called by muse, mutect2, varscan2
- KAT6B | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 208/419 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as rs762226616; called by muse, varscan2
- KAZALD1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs775029615; called by muse, mutect2, varscan2
- KCNA5 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 272/447 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906284; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KCNH7 | c.3101G>C p.R1034T | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59797751; called by muse, mutect2, varscan2
- KCP | c.3553G>A p.D1185N (on ENST00000620378; = p.D1309N on NM_001366122.1) | Missense Mutation (SNP) | VAF 169/292 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1366302624; called by muse, mutect2, varscan2
- KCTD15 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 336/528 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754403939; called by muse, mutect2
- KDM3A | c.3412G>T p.G1138* | Nonsense Mutation (SNP) | VAF 9/282 reads (3%) | catalogued as COSV100461049; called by muse, mutect2
- KIF13B | c.3935C>T p.A1312V | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs1254164152; called by muse, mutect2
- KIF19 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 355/703 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs746682527; called by muse, mutect2, varscan2
- KIF1A | c.4829C>T p.P1610L (on ENST00000320389 / NM_001379639.1; = p.P1602L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/679 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57490264, COSV57494703; called by muse, mutect2, varscan2
- KIF25 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 221/369 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.146); catalogued as rs1409503843; called by muse, mutect2, varscan2
- KIF3C | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 139/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755172492; called by muse, mutect2, varscan2
- KLHDC8B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748760709; called by muse, mutect2, varscan2
- KLHL1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 349/531 reads (66%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100917689; called by muse, mutect2, varscan2
- KLHL32 | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs764854468; called by muse, mutect2, varscan2
- KLKB1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs1414189090; called by muse, mutect2, varscan2
- KMT2A | c.10819C>T p.P3607S | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs782393372, COSV63285518; called by muse, mutect2, varscan2
- KMT2A | c.10820C>T p.P3607L | Missense Mutation (SNP) | VAF 126/333 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.117); catalogued as rs1555048916; called by muse, mutect2, varscan2
- KMT2D | c.10025G>A p.R3342H | Missense Mutation (SNP) | VAF 233/352 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as rs1397945395; called by muse, mutect2, varscan2
- KNL1 | c.3127C>T p.P1043S (on ENST00000346991 / NM_170589.5; = p.P1017S on NM_144508.5) | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as rs201242765; called by muse, mutect2, varscan2
- KRCC1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100712860; called by muse, mutect2, varscan2
- KRT28 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 285/632 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.379); catalogued as COSV60683465; called by muse, mutect2
- KRT72 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1345059963; called by muse, mutect2, varscan2
- KRTAP21-3 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 76/110 reads (69%) | PolyPhen benign (0.3); catalogued as rs1028461122; called by muse, mutect2, varscan2
- LARP4B | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 74/202 reads (37%) | catalogued as COSV60220411; called by muse, mutect2, varscan2
- LATS2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 316/587 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66878885; called by muse, mutect2, varscan2
- LDHD | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs760873322; called by muse, mutect2, varscan2
- LEUTX | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 160/279 reads (57%) | catalogued as COSV101203197; called by muse, mutect2, varscan2
- LGI1 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 84/362 reads (23%) | catalogued as COSV65057676; called by muse, mutect2, varscan2
- LNPEP | c.2885C>T p.T962I | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99183461; called by muse, mutect2, varscan2
- LPA | c.4444C>T p.P1482S | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.384); catalogued as COSV60300220; called by muse, mutect2, varscan2
- LRFN5 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV99984919; called by muse, mutect2, varscan2
- LRIG2 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 170/265 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63162158; called by muse, mutect2, varscan2
- LRIT1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 238/520 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs776008586, COSV64512551; called by muse, mutect2, varscan2
- LRP1B | c.11591C>T p.S3864L | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67189713, COSV67221038; called by muse, mutect2, varscan2
- LRP1B | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 174/270 reads (64%) | catalogued as COSV67288453; called by muse, mutect2, varscan2
- LRRK2 | c.3668G>A p.R1223K | Missense Mutation (SNP) | VAF 188/314 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.692); catalogued as COSV54141881; called by muse, varscan2
- LRRK2 | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs373268136, COSV54147088; called by muse, mutect2, varscan2
- LTBP3 | c.3679C>T p.R1227C (on ENST00000301873 / NM_001130144.3; = p.R1180C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 242/521 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1397716583; called by muse, mutect2, varscan2
- LUC7L | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 177/301 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs996609757, COSV53457744; called by muse, mutect2, varscan2
- MACF1 | c.19130C>T p.S6377F (on ENST00000372915; = p.S4422F on NM_012090.5) | Missense Mutation (SNP) | VAF 111/152 reads (73%) | catalogued as COSV99241588; called by muse, mutect2, varscan2
- MADD | c.2800C>T p.R934* | Nonsense Mutation (SNP) | VAF 110/212 reads (52%) | catalogued as COSV60623213; called by muse, varscan2
- MAFA | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198164403; called by muse, mutect2, varscan2
- MAGEA11 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1173199954; called by muse, mutect2, varscan2
- MAP3K20 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 117/168 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs755881907; called by muse, mutect2, varscan2
- MAP3K3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 161/356 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.083); catalogued as rs747980360; called by muse, mutect2, varscan2
- MAP7 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.097); catalogued as rs1177867890; called by muse, mutect2, varscan2
- MAPK7 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 168/696 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs755118879; called by muse, mutect2, varscan2
- MBD1 | c.1597G>A p.G533S (on ENST00000269468 / NM_001323950.1; = p.G431S on NM_002384.2) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV99495806; called by muse, mutect2, varscan2
- MCAM | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 211/472 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs780145542; called by muse, mutect2, varscan2
- MCPH1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV60910369; called by muse, mutect2, varscan2
- MED1 | c.4097C>T p.S1366F | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs778850350; called by muse, mutect2, varscan2
- MED23 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 58/180 reads (32%) | catalogued as COSV100644763; called by muse, mutect2, varscan2
- MEGF10 | c.2124G>A p.W708* | Nonsense Mutation (SNP) | VAF 83/302 reads (27%) | catalogued as COSV57257537; called by muse, mutect2, varscan2
- MEGF10 | c.3140G>A p.G1047D | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1386977065; called by muse, mutect2, varscan2
- MFSD2B | c.431G>A p.W144* | Nonsense Mutation (SNP) | VAF 152/418 reads (36%) | catalogued as rs1244985239, COSV100601230; called by muse, mutect2, varscan2
- MFSD6L | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 96/465 reads (21%) | catalogued as rs1359838904, COSV61001221; called by muse, mutect2, varscan2
- MICAL1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 136/378 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747384815; called by muse, mutect2, varscan2
- MIER2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 261/413 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as rs764352723, COSV53396339; called by muse, mutect2, varscan2
- MLH1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV51621137; called by muse, mutect2, varscan2
- MLPH | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs369604551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPPED2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 120/207 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs1209653458; called by muse, mutect2, varscan2
- MRC2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 282/572 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765509790, COSV57640857; called by muse, mutect2, varscan2
- MRGPRX4 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs867583881, COSV58591423; called by muse, mutect2, varscan2
- MS4A14 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 182/396 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV55734556; called by muse, mutect2, varscan2
- MS4A7 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 158/360 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV55730886; called by muse, mutect2, varscan2
- MSH6 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 146/232 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1553412749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCH1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 447/866 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1405799185; called by muse, mutect2, varscan2
- MTERF4 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54089697; called by muse, mutect2, varscan2
- MTHFD1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 221/482 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV53700780; called by muse, mutect2, varscan2
- MTRR | c.1904C>T p.S635F (on ENST00000264668; = p.S608F on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/485 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV52946693; called by muse, mutect2
- MUC16 | c.43228G>A p.E14410K | Missense Mutation (SNP) | VAF 97/302 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66694294; called by muse, mutect2, varscan2
- MUC16 | c.38951C>T p.P12984L | Missense Mutation (SNP) | VAF 81/143 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs764851118; called by muse, mutect2, varscan2
- MUC16 | c.29911C>T p.L9971F | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.829); catalogued as COSV67464861; called by muse, mutect2, varscan2
- MUC17 | c.6943G>T p.E2315* | Nonsense Mutation (SNP) | VAF 185/296 reads (63%) | catalogued as COSV60282532; called by muse, mutect2, varscan2
- MUC4 | c.12644C>T p.S4215F | Missense Mutation (SNP) | VAF 119/786 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV57805827; called by muse, mutect2, varscan2
- MUS81 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 126/298 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57259988; called by muse, mutect2, varscan2
- MYBL2 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 335/651 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs773951994; called by muse, mutect2, varscan2
- MYH13 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 185/399 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs754289824; called by muse, mutect2, varscan2
- MYH7 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 240/469 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62523920; called by muse, mutect2, varscan2
- MYO5B | c.5170C>T p.R1724W | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201349623, COSV53229394; called by muse, mutect2, varscan2
- MYO5C | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs767982964, COSV55911354; called by muse, mutect2, varscan2
- MYO7B | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 265/409 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs1318431934; called by muse, mutect2, varscan2
- NAALADL1 | c.862T>C p.F288L | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV60524078; called by muse, mutect2, varscan2
- NAPA | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 169/265 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV54550299; called by muse, mutect2, varscan2
- NCAM2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99523199; called by muse, mutect2, varscan2
- NCOR1 | c.5203G>A p.D1735N | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.132); catalogued as rs1567787429, COSV51964181; called by muse, mutect2, varscan2
- NDN | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs767688029, COSV59359761; called by muse, mutect2, varscan2
- NEB | c.4069C>T p.H1357Y | Missense Mutation (SNP) | VAF 105/363 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51099188; called by muse, mutect2, varscan2
- NELFE | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 188/427 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.273); catalogued as COSV100952564; called by muse, mutect2, varscan2
- NES | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 318/468 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs1259433194, COSV63961316; called by muse, mutect2, varscan2
- NFKB1 | c.1235C>T p.P412L (on ENST00000394820 / NM_001382627.1; = p.P413L on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV99896566; called by muse, mutect2, varscan2
- NFKB2 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 183/409 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1485873314; called by muse, mutect2, varscan2
- NGRN | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 240/470 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs749052366; called by muse, varscan2
- NHLRC1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 113/484 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV61481447; called by muse, mutect2, varscan2
- NLRP8 | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 171/298 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52591036; called by muse, mutect2, varscan2
- NLRP9 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as rs764727195; called by muse, mutect2, varscan2
- NOTCH1 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 874/874 reads (100%) | catalogued as COSV53095145; called by muse, mutect2, varscan2
- NOTCH3 | c.4724C>T p.P1575L | Missense Mutation (SNP) | VAF 221/351 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV54630977, COSV99656532; called by muse, mutect2, varscan2
- NOTCH4 | c.2447G>A p.R816K | Missense Mutation (SNP) | VAF 186/449 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.394); catalogued as rs1331335302, COSV66683735; called by muse, mutect2, varscan2
- NPEPPS | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 149/319 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV59102476; called by muse, mutect2, varscan2
- NPTN | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs371877856; called by muse, mutect2, varscan2
- NR1I2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 284/599 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as rs538208001; called by muse, mutect2, varscan2
- NRAP | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100748679; called by muse, mutect2, varscan2
- NRIP1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 218/326 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568941056, COSV59657077; called by muse, varscan2
- NXPE3 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 128/238 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1387067609; called by muse, mutect2, varscan2
- NXPH1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 277/483 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68312575; called by muse, mutect2, varscan2
- NXPH2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 204/312 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.186); catalogued as rs1350571894; called by muse, mutect2, varscan2
- NYAP1 | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs1373084421; called by muse, mutect2, varscan2
- OBI1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as COSV56144273, COSV56147577, COSV99932564; called by muse, mutect2, varscan2
- OBSCN | c.21379C>T p.Q7127* | Nonsense Mutation (SNP) | VAF 188/526 reads (36%) | catalogued as rs565158699; called by muse, mutect2, varscan2
- OLFM3 | c.977G>A p.R326Q (on ENST00000338858 / NM_001288821.1; = p.R306Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1278883199, COSV58800476; called by muse, mutect2, varscan2
- OLFML1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100252649; called by muse, mutect2, varscan2
- OR10T2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV57782393; called by muse, mutect2, varscan2
- OR11H7 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 166/351 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1335282360; called by muse, mutect2, varscan2
- OR13A1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 330/661 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as rs747984390; called by muse, mutect2, varscan2
- OR13C8 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs376226082; called by muse, mutect2, varscan2
- OR1S2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 199/371 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV56919856; called by muse, mutect2, varscan2
- OR2A14 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs1323672350, COSV101376445; called by muse, mutect2, varscan2
- OR2T33 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 268/602 reads (45%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.654); catalogued as COSV100531710; called by muse, mutect2, varscan2
- OR4C11 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV56354911; called by muse, mutect2, varscan2
- OR4D1 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52125790; called by muse, mutect2, varscan2
- OR51A4 | c.410T>G p.I137S | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV66749216; called by muse, varscan2
- OR5D3P | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1230572207; called by muse, varscan2
- OR7G3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 157/238 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1355036281; called by muse, mutect2
- ORC1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 170/282 reads (60%) | catalogued as rs141971656; called by muse, mutect2, varscan2
- OVCH2 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 160/283 reads (57%) | catalogued as COSV71952881; called by muse, mutect2, varscan2
- OXSR1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 141/142 reads (99%) | catalogued as COSV61258519; called by muse, mutect2, varscan2
- PACC1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 156/256 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1427042473; called by muse, mutect2, varscan2
- PAK2 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 129/313 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1221732915, COSV59082025; called by muse, mutect2, varscan2
- PAK6 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 95/584 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759863961; called by muse, mutect2, varscan2
- PAN3 | c.1121G>C p.S374T | Missense Mutation (SNP) | VAF 173/349 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs768803539; called by muse, mutect2, varscan2
- PARVA | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.459); catalogued as rs772353437; called by muse, mutect2, varscan2
- PCDH15 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 149/330 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs753457449, COSV100226452, COSV57270179; called by muse, mutect2, varscan2
- PCDHA2 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 178/369 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs782298789; called by muse, mutect2, varscan2
- PCDHA5 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 233/456 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as rs868985416, COSV65358963; called by muse, mutect2, varscan2
- PCDHB12 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 175/396 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as rs146148949; called by muse, mutect2, varscan2
- PCDHB12 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 236/990 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs1554286997; called by muse, mutect2, varscan2
- PCDHB2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 229/473 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs369245601; called by muse, mutect2, varscan2
- PCDHGA2 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 259/523 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.287); catalogued as COSV54044781; called by muse, mutect2, varscan2
- PCDHGA4 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV53893115; called by muse, mutect2, varscan2
- PCDHGB2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 177/409 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758998647, COSV53916603; called by muse, mutect2, varscan2
- PCED1B | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 210/324 reads (65%) | catalogued as COSV71395353; called by muse, varscan2
- PCM1 | c.5339C>T p.P1780L | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs1240485455; called by muse, mutect2, varscan2
- PCNX2 | c.2222+1G>A p.X741_splice | Splice Site (SNP) | VAF 38/143 reads (27%) | catalogued as COSV50875805; called by muse, mutect2, varscan2
- PCNX2 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.105); catalogued as rs781218699; called by muse, mutect2, varscan2
- PCSK5 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 257/717 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.842); catalogued as COSV65095354, COSV65096369; called by muse, mutect2, varscan2
- PCSK5 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 258/716 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1356768087; called by muse, mutect2, varscan2
- PCSK7 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 185/763 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775479361; called by muse, mutect2, varscan2
- PDCD11 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 178/315 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370054051; called by muse, mutect2, varscan2
- PDE11A | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs528467210; called by muse, mutect2, varscan2
- PDE8A | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs779203534; called by muse, mutect2, varscan2
- PDZD2 | c.7589C>T p.S2530L | Missense Mutation (SNP) | VAF 192/647 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs776310308; called by muse, mutect2, varscan2
- PDZRN3 | c.1187A>T p.Y396F | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV55211636; called by muse, mutect2, varscan2
- PEG10 | c.11G>A p.R4Q (on ENST00000482108 / NM_001040152.2; = p.R38Q on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/382 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV71787963; called by muse, varscan2
- PEG3 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99690806; called by muse, mutect2
- PERM1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 170/556 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs937415720, COSV58021013; called by muse, mutect2
- PGGT1B | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 178/366 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV56975798; called by muse, mutect2, varscan2
- PGLYRP3 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs779510247; called by muse, mutect2, varscan2
- PGLYRP3 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.851); catalogued as rs371291514; called by muse, mutect2, varscan2
- PGM1 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 171/264 reads (65%) | catalogued as rs868866342; called by muse, mutect2, varscan2
- PHRF1 | c.2318C>T p.T773I (on ENST00000264555 / NM_001286581.2; = p.T772I on NM_020901.4) | Missense Mutation (SNP) | VAF 200/551 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1022028722; called by muse, varscan2
- PI4KB | c.457G>A p.E153K (on ENST00000368873 / NM_001369623.1; = p.E165K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/449 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55020477; called by muse, mutect2, varscan2
- PIGQ | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 149/474 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV99215946; called by muse, mutect2, varscan2
- PKD1 | c.9275C>T p.A3092V | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1447121645; called by muse, mutect2, varscan2
- PLD2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558449929, COSV99562103; called by muse, mutect2, varscan2
- PLEC | c.11677G>A p.E3893K (on ENST00000322810 / NM_201380.4; = p.E3783K on NM_000445.5) | Missense Mutation (SNP) | VAF 143/429 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs369563702; called by muse, mutect2, varscan2
- PLEC | c.6832G>A p.E2278K (on ENST00000322810 / NM_201380.4; = p.E2168K on NM_000445.5) | Missense Mutation (SNP) | VAF 346/569 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV59657170; called by muse, mutect2, varscan2
- PLEKHA7 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 207/380 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV60580794; called by muse, mutect2, varscan2
- PLEKHH3 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 186/441 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs754575468; called by muse, mutect2
- PLXNB2 | c.3034C>T p.Q1012* | Nonsense Mutation (SNP) | VAF 249/391 reads (64%) | catalogued as COSV63784172; called by muse, mutect2, varscan2
- PLXNB2 | c.2773C>T p.Q925* | Nonsense Mutation (SNP) | VAF 163/512 reads (32%) | catalogued as COSV63781754, COSV63785269; called by muse, mutect2, varscan2
- PLXNB3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 434/434 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs782754359; called by muse, mutect2, varscan2
- PMEPA1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 136/666 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV55696547; called by muse, mutect2
- PNPLA8 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs748773667; called by muse, mutect2, varscan2
- POLR2E | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 146/474 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.835); catalogued as rs779428291, COSV53125782; called by muse, mutect2, varscan2
- POLR2E | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 147/480 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.444); catalogued as COSV53123458; called by muse, mutect2, varscan2
- PPARGC1A | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1259694270, COSV53533428; called by muse, mutect2, varscan2
- PPFIBP2 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 143/270 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs756766040, COSV55082744; called by muse, mutect2, varscan2
- PPP1R13B | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52453503, COSV99157403; called by muse, mutect2, varscan2
- PPP1R3A | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 198/296 reads (67%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs267601242; called by muse, mutect2, varscan2
- PPP1R9B | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 206/457 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs769869474; called by muse, mutect2, varscan2
- PPRC1 | c.4372C>T p.L1458F | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs759287093; called by muse, mutect2, varscan2
- PRAME | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as rs768093842; called by muse, mutect2, varscan2
- PRB4 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV54398920; called by muse, varscan2
- PRDM15 | c.3458C>T p.S1153F | Missense Mutation (SNP) | VAF 252/407 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV54150568; called by muse, mutect2, varscan2
- PRKCD | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57852051, COSV57852572; called by muse, mutect2, varscan2
- PRR27 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.225); catalogued as rs1245747471; called by muse, mutect2, varscan2
- PRRX1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53410732, COSV53413286; called by muse, mutect2, varscan2
- PRUNE2 | c.8722C>T p.H2908Y | Missense Mutation (SNP) | VAF 240/400 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56315764; called by muse, mutect2, varscan2
- PSD3 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs1339284909; called by muse, mutect2, varscan2
- PSG7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 166/277 reads (60%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); catalogued as rs1370553446, COSV68445186; called by muse, mutect2, varscan2
- PSMD8 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 163/474 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs867351891; called by muse, mutect2, varscan2
- PYCARD | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 175/537 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs1270437011, COSV56008656; called by muse, mutect2, varscan2
- QPCTL | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 248/398 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375848663, COSV50003656; called by muse, mutect2, varscan2
- RADIL | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 486/773 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456771227; called by muse, mutect2, varscan2
- RALGAPA1 | c.5936C>G p.A1979G | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51875270; called by muse, mutect2, varscan2
- RASD2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 111/344 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs193065178, COSV53351855; called by muse, mutect2, varscan2
- RASEF | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 248/391 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1314704396; called by muse, mutect2, varscan2
- RASGRP1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 114/225 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV100172126; called by muse, mutect2, varscan2
- RASSF8 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV51455263; called by muse, mutect2, varscan2
- RBAK | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 176/492 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV62331441; called by muse, mutect2
- RBM26 | c.1931C>T p.P644L (on ENST00000438737 / NM_001366735.2; = p.P641L on NM_022118.5) | Missense Mutation (SNP) | VAF 139/516 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.039); catalogued as rs1346701287; called by muse, mutect2, varscan2
- REG1B | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs377645272; called by muse, mutect2, varscan2
- REG3G | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 178/330 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99709651; called by muse, mutect2, varscan2
- RELN | c.4439G>A p.G1480D | Missense Mutation (SNP) | VAF 193/288 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100632886; called by muse, mutect2, varscan2
- RET | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 288/648 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.049); catalogued as COSV60695130; called by muse, mutect2, varscan2
- RFX6 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 102/165 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs767918169, COSV60583999; called by muse, mutect2, varscan2
- RGS12 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 153/244 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100122711; called by muse, mutect2, varscan2
- RGS13 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs531861902, COSV101232296; called by muse, mutect2, varscan2
- RGS14 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1355976661; called by muse, mutect2, varscan2
- RGS3 | c.2546C>T p.A849V (on ENST00000350696 / NM_001282923.2; = p.A568V on NM_130795.4) | Missense Mutation (SNP) | VAF 574/898 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1168147157; called by muse, mutect2, varscan2
- RNF112 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 227/485 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1287338005; called by muse, mutect2, varscan2
- RNF175 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as rs1405535019; called by muse, mutect2, varscan2
- RNF186 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 104/151 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1278681277; called by muse, mutect2, varscan2
- RNF213 | c.7867C>T p.Q2623* | Nonsense Mutation (SNP) | VAF 78/354 reads (22%) | catalogued as COSV60404079; called by muse, mutect2, varscan2
- RNF213 | c.10995G>A p.W3665* | Nonsense Mutation (SNP) | VAF 135/278 reads (49%) | catalogued as COSV100301843, COSV60407081; called by muse, mutect2, varscan2
- RNF214 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs1415455055; called by muse, mutect2, varscan2
- RNF6 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 174/364 reads (48%) | catalogued as COSV60420082; called by muse, mutect2, varscan2
- ROCK2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55086643; called by muse, mutect2, varscan2
- RP1L1 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs747175878, COSV66752706; called by muse, mutect2, varscan2
- RRP1B | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 127/357 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs911202990; called by muse, mutect2, varscan2
- RSC1A1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs757473323, COSV60781347; called by muse, mutect2, varscan2
- RSF1 | c.4078C>A p.P1360T | Missense Mutation (SNP) | VAF 159/360 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.513); catalogued as rs143199325; called by muse, mutect2, varscan2
- RUSF1 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 283/420 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779477336; called by muse, mutect2, varscan2
- RYR1 | c.8758C>T p.R2920* | Nonsense Mutation (SNP) | VAF 134/352 reads (38%) | catalogued as CM144265; called by muse, mutect2, varscan2
- RYR1 | c.9281C>T p.S3094F | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62115285; called by muse, mutect2, varscan2
- S1PR2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 151/391 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM161789; called by muse, mutect2, varscan2
- SAMD15 | c.1690-1G>A p.X564_splice | Splice Site (SNP) | VAF 92/201 reads (46%) | catalogued as rs762835717; called by muse, mutect2, varscan2
- SCG3 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as rs374517191; called by muse, mutect2, varscan2
- SCN4A | c.5455C>T p.P1819S | Missense Mutation (SNP) | VAF 329/677 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV71128915; called by muse, mutect2, varscan2
- SCN7A | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV69268957, COSV69269209; called by muse, mutect2, varscan2
- SCNN1B | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV56305543; called by muse, mutect2, varscan2
- SCRIB | c.2329G>A p.G777S | Missense Mutation (SNP) | VAF 224/362 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458565544; called by muse, mutect2, varscan2
- SCUBE3 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747128199, COSV51458521; called by muse, mutect2, varscan2
- SDS | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 232/454 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV57453102; called by muse, mutect2, varscan2
- SESN2 | c.750G>A p.G250= | Splice Region (SNP) | VAF 179/274 reads (65%) | catalogued as COSV53427543; called by muse, mutect2, varscan2
- SFN | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 137/404 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as rs777841410, COSV100212842; called by muse, mutect2, varscan2
- SH2D3A | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 173/556 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs374798192; called by muse, mutect2, varscan2
- SLC10A2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866026770, COSV55358409; called by muse, mutect2, varscan2
- SLC12A2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 197/773 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV52470890; called by muse, mutect2, varscan2
- SLC18A1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52349689, COSV99368345; called by muse, mutect2, varscan2
- SLC1A1 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.211); catalogued as COSV52055984; called by muse, mutect2, varscan2
- SLC26A8 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV62888178; called by muse, mutect2, varscan2
- SLC27A1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 178/605 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs867992648; called by muse, mutect2, varscan2
- SLC28A1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs149246522, COSV54481917; ClinVar: affects; called by muse, mutect2, varscan2
- SLC28A3 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761056097; called by muse, mutect2, varscan2
- SLC41A2 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 122/482 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs202226051, COSV51604203; called by muse, mutect2, varscan2
- SLC49A3 | c.1363G>A p.E455K (on ENST00000404286 / NM_001294341.2; = p.E454K on NM_032219.4) | Missense Mutation (SNP) | VAF 158/475 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as rs541751641; called by muse, mutect2, varscan2
- SLC5A1 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as CM991140, COSV56683414; called by muse, mutect2, varscan2
- SLC5A12 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1311613092; called by muse, mutect2
- SLC5A2 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs749300905, CM087251, COSV100392993; called by muse, mutect2, varscan2
- SLC6A18 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 159/970 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as rs1264682102, COSV57253818; called by muse, mutect2, varscan2
- SLC9A4 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV99763336; called by muse, mutect2, varscan2
- SLC9C1 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59884763; called by muse, mutect2, varscan2
- SLCO1A2 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56597637; called by muse, mutect2, varscan2
- SLCO5A1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 143/407 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753503254; called by muse, mutect2, varscan2
- SLFN11 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV57697855; called by muse, mutect2, varscan2
- SLMAP | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55852889; called by muse, mutect2, varscan2
- SMOC2 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 216/340 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs150344348; called by muse, mutect2, varscan2
- SNAP91 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52126702; called by muse, mutect2, varscan2
- SNRNP70 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 226/618 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.059); catalogued as rs1316594899; called by muse, mutect2
- SOGA3 | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1305746769, COSV100847008; called by muse, mutect2, varscan2
- SOGA3 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 159/475 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1472866629; called by muse, mutect2, varscan2
- SOX13 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 60/169 reads (36%) | catalogued as COSV65826759; called by muse, mutect2, varscan2
- SPAST | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM164813; called by muse, mutect2, varscan2
- SPATA46 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343601769; called by muse, mutect2, varscan2
- SPG11 | c.3892G>A p.A1298T | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56001845; called by muse, mutect2, varscan2
- SPOCK3 | c.914G>A p.W305* | Nonsense Mutation (SNP) | VAF 100/167 reads (60%) | catalogued as COSV62737743; called by muse, mutect2, varscan2
- SPSB3 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 181/306 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as rs943548324; called by muse, mutect2, varscan2
- SRBD1 | c.2057T>G p.V686G | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99765732; called by muse, mutect2, varscan2
- SRRM2 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57074214; called by muse, mutect2, varscan2
- SRRM2 | c.5272A>G p.R1758G | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV57080747; called by muse, mutect2, varscan2
- SRRT | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 167/261 reads (64%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs558821321; called by muse, mutect2, varscan2
- SSH1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1167626582; called by muse, mutect2, varscan2
- SSH1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143523576; called by muse, mutect2, varscan2
- ST7 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 174/282 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV99623296; called by muse, varscan2
- STAC3 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 225/347 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV100234808, COSV60414697; called by muse, mutect2, varscan2
- STMN3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 175/373 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as rs984663440, COSV64247122; called by muse, mutect2, varscan2
- SUN3 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 281/476 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV52053277; called by muse, mutect2, varscan2
- SUOX | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs754775064; called by muse, mutect2, varscan2
- SYT1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 222/339 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54032324; called by muse, mutect2, varscan2
- TAGAP | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 230/389 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553431311; called by muse, mutect2, varscan2
- TANC1 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 41/142 reads (29%) | catalogued as COSV55095690, COSV55098839; called by muse, mutect2, varscan2
- TANC1 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1559444922; called by muse, mutect2, varscan2
- TASOR | c.4711C>G p.Q1571E (on ENST00000355628 / NM_001365636.2; = p.Q1195E on NM_015224.3) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV58300927; called by muse, mutect2
- TATDN2 | c.2254del p.R752Vfs*26 (on ENST00000287652; = p.R752Vfs*29 on NM_014760.4) | Frame Shift Del (DEL) | VAF 91/194 reads (47%) | catalogued as COSV99813299; called by mutect2, pindel*, varscan2
- TBC1D22B | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 148/601 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65142941; called by muse, mutect2, varscan2
- TBX15 | c.1210C>T p.R404* (on ENST00000369429 / NM_001330677.2; = p.R298* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 168/247 reads (68%) | catalogued as rs1450879747, COSV52872945; called by muse, mutect2, varscan2
- TBX22 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV64787291; called by muse, mutect2, varscan2
- TBXAS1 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1439722090; called by muse, mutect2, varscan2
- TEKT5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 107/170 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768751924; called by muse, varscan2
- TENM2 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 158/307 reads (51%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.992); catalogued as rs146756155; called by muse, mutect2, varscan2
- TENM3 | c.4192G>A p.V1398M | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1489613177; called by muse, mutect2, varscan2
- TEX29 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 155/663 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV52096153; called by muse, mutect2, varscan2
- TFR2 | c.1180G>C p.G394R | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs557506122; called by muse, mutect2, varscan2
- TFRC | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 178/331 reads (54%) | catalogued as COSV64055775; called by muse, mutect2, varscan2
- TG | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200687678, COSV99602604; called by muse, mutect2, varscan2
- THBS1 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs143907582; called by muse, mutect2, varscan2
- THEMIS2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 247/399 reads (62%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs750284195; called by muse, mutect2, varscan2
- TJP1 | c.3734C>T p.P1245L | Missense Mutation (SNP) | VAF 156/596 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.962); catalogued as rs753800615; called by muse, mutect2, varscan2
- TJP2 | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 347/560 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773974961; called by muse, mutect2, varscan2
- TLE1 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 142/493 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs141647936; called by muse, mutect2, varscan2
- TMEM116 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 128/240 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1314366033; called by muse, mutect2, varscan2
- TMEM126B | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs918262592; called by muse, mutect2, varscan2
- TMEM132B | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 168/355 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as COSV54774404, COSV54774594; called by muse, mutect2, varscan2
- TMEM132D | c.3186G>C p.R1062S | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV101242879; called by muse, varscan2
- TMEM132D | c.3061G>A p.G1021R | Missense Mutation (SNP) | VAF 194/396 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV67162394; called by muse, varscan2
- TMEM222 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 240/355 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1447120807, COSV65027134; called by muse, mutect2, varscan2
- TMEM222 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 245/361 reads (68%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.074); catalogued as rs754715407, COSV65027003; called by muse, mutect2, varscan2
- TMEM255B | c.80G>A p.W27* | Nonsense Mutation (SNP) | VAF 191/759 reads (25%) | catalogued as rs775950607; called by muse, mutect2, varscan2
- TMEM45A | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV100058481; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 42/69 reads (61%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TMPRSS11F | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 78/270 reads (29%) | catalogued as rs761964521, COSV62465277; called by muse, mutect2, varscan2
- TMUB2 | c.359C>T p.S120F (on ENST00000538716 / NM_001353177.2; = p.S100F on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/399 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs373074214; called by muse, mutect2, varscan2
- TNC | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 189/710 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1043186450, COSV60787191; called by muse, mutect2, varscan2
- TNFRSF19 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 208/443 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs760735308; called by muse, mutect2, varscan2
- TNR | c.3800C>T p.S1267F | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293553965, COSV54884572; called by muse, mutect2, varscan2
- TNRC18 | c.7048G>A p.E2350K | Missense Mutation (SNP) | VAF 187/534 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.643); catalogued as rs532506712; called by muse, mutect2, varscan2
- TOP2A | c.4522C>T p.P1508S | Missense Mutation (SNP) | VAF 151/275 reads (55%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.017); catalogued as rs1472043534; called by muse, mutect2, varscan2
- TPTE2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); catalogued as rs754090436; called by muse, mutect2, varscan2
- TRARG1 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770378061; called by muse, mutect2, varscan2
- TRBV6-1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs1432316988; called by muse, mutect2, varscan2
- TRIB3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 282/592 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs375609488, COSV99423851; called by muse, varscan2
- TRIM26 | c.842A>T p.K281I | Missense Mutation (SNP) | VAF 100/381 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs753468998, COSV70983540; called by mutect2, varscan2
- TRIM51 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs753444898; called by muse, mutect2, varscan2
- TRPA1 | c.2195del p.P732Lfs*2 | Frame Shift Del (DEL) | VAF 90/309 reads (29%) | catalogued as COSV51555331; called by mutect2, pindel, varscan2
- TRPM3 | c.1753C>T p.R585C (on ENST00000357533 / NM_001366142.2; = p.R418C on NM_020952.6) | Missense Mutation (SNP) | VAF 227/700 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs1009688777, COSV62589864; called by muse, mutect2, varscan2
- TRPM3 | c.1307G>A p.G436E (on ENST00000357533 / NM_001366142.2; = p.G281E on NM_020952.6) | Missense Mutation (SNP) | VAF 170/588 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs1220641422; called by muse, mutect2, varscan2
- TSBP1 | c.649G>A p.D217N (on ENST00000617061; = p.D220N on NM_006781.5) | Missense Mutation (SNP) | VAF 161/325 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66660502; called by muse, mutect2, varscan2
- TSGA10 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs368503596, COSV61822140; called by muse, mutect2, varscan2
- TSKS | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1281827100, COSV55873322; called by muse, mutect2, varscan2
- TSNARE1 | c.984G>A p.P328= | Splice Region (SNP) | VAF 119/198 reads (60%) | catalogued as rs780726823; called by muse, varscan2
- TTC7A | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 357/542 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0.077); catalogued as COSV55409561; called by muse, mutect2, varscan2
- TTLL7 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs267598737, COSV53088658; called by muse, mutect2, varscan2
- TTN | c.91433G>A p.R30478K (on ENST00000591111; = p.R23054K on NM_003319.4) | Missense Mutation (SNP) | VAF 63/227 reads (28%) | PolyPhen benign (0.003); catalogued as rs183151656, COSV100601928; called by muse, mutect2, varscan2
- TTN | c.39343C>T p.H13115Y (on ENST00000591111; = p.H5691Y on NM_003319.4) | Missense Mutation (SNP) | VAF 26/242 reads (11%) | PolyPhen possibly damaging (0.592); catalogued as rs766470098, COSV59905634; called by muse, varscan2
- TTN | c.7255A>G p.K2419E (on ENST00000591111; = p.K2373E on NM_003319.4) | Missense Mutation (SNP) | VAF 107/344 reads (31%) | PolyPhen benign (0.121); catalogued as COSV60212365; called by muse, mutect2, varscan2
- TUBB4A | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 52/224 reads (23%) | catalogued as COSV51153909; called by muse, mutect2, varscan2
- TUFM | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs1233129055; called by muse, mutect2, varscan2
- TYR | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 233/470 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372689330, COSV54471180; called by muse, mutect2, varscan2
- UBAP2L | c.128C>G p.S43W | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV55173711; called by muse, mutect2, varscan2
- UBE3C | c.1943G>C p.R648T | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV61952847; called by muse, mutect2, varscan2
- UBR4 | c.5392G>A p.E1798K | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.027); catalogued as rs1391476073; called by muse, mutect2, varscan2
- UGP2 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 131/232 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55440915; called by muse, mutect2, varscan2
- UNC79 | c.3268G>A p.A1090T (on ENST00000393151 / NM_001346218.2; = p.A913T on NM_020818.5) | Missense Mutation (SNP) | VAF 334/682 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.853); catalogued as COSV56416484; called by muse, varscan2
- USF3 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs772357952, COSV100325918; called by muse, mutect2, varscan2
- USH2A | c.7601G>A p.G2534E | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs867568375; called by muse, mutect2, varscan2
- USH2A | c.2629C>T p.L877F | Missense Mutation (SNP) | VAF 104/355 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV56386155; called by muse, mutect2, varscan2
- USP17L10 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.829); catalogued as rs530078335; called by muse, mutect2, varscan2
- USP34 | c.4508C>G p.S1503C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs756378931, COSV68404211; called by muse, mutect2, varscan2
- USP36 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 115/467 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs992345103; called by muse, mutect2, varscan2
- USP5 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781905870, COSV99979133; called by muse, mutect2, varscan2
- USP6 | c.1424G>A p.W475* | Nonsense Mutation (SNP) | VAF 99/383 reads (26%) | catalogued as rs1376515778, COSV51475898; called by muse, mutect2, varscan2
- VARS1 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 325/755 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV63304634; called by muse, mutect2, varscan2
- VAV2 | c.1109C>T p.A370V (on ENST00000371850 / NM_001134398.2; = p.A365V on NM_003371.4) | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs754562539; called by muse, mutect2
- VPS13D | c.7307G>A p.S2436N | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV50668124; called by muse, mutect2, varscan2
- VRTN | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 248/526 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56440388; called by muse, mutect2, varscan2
- VWA5B1 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1214990250; called by muse, varscan2
- VWCE | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 230/470 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV57111942; called by muse, mutect2, varscan2
- WDR35 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 100/175 reads (57%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs776905427, COSV55605374; called by muse, mutect2, varscan2
- WDR46 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 313/681 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs141256696; called by muse, mutect2, varscan2
- WNK2 | c.4244G>A p.G1415E (on ENST00000297954 / NM_001282394.1; = p.G1378E on NM_006648.3) | Missense Mutation (SNP) | VAF 480/779 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1215679000; called by muse, mutect2, varscan2
- WWTR1 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs963468962; called by muse, mutect2, varscan2
- XIRP2 | c.3872G>A p.G1291E (on ENST00000628543; = p.G1466E on NM_152381.6) | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1392730095; called by muse, mutect2, varscan2
- XPOT | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 86/142 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1260392101, COSV100225686; called by muse, mutect2, varscan2
- YBX3 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 165/516 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs989330977; called by muse, mutect2, varscan2
- YJU2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs1195375473; called by muse, mutect2, varscan2
- ZBED9 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 230/448 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV71729700; called by muse, mutect2, varscan2
- ZBTB32 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 146/455 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs141083613, COSV52891606; called by muse, mutect2, varscan2
- ZBTB34 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 81/639 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV59860370; called by muse, mutect2, varscan2
- ZC3H6 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 186/310 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV59667046; called by muse, mutect2, varscan2
- ZEB1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 146/341 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58042365; called by muse, mutect2, varscan2
- ZNF180 | c.1595G>T p.W532L | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99659950; called by muse, mutect2, varscan2
- ZNF248 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.44); catalogued as rs143473555; called by muse, mutect2, varscan2
- ZNF273 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 71/794 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60397700; called by muse, mutect2
- ZNF281 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 213/324 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1339294165, COSV54169050; called by muse, mutect2, varscan2
- ZNF318 | c.4235G>A p.G1412E | Missense Mutation (SNP) | VAF 216/439 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416145784; called by muse, mutect2, varscan2
- ZNF32 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as COSV65642029; called by muse, mutect2, varscan2
- ZNF385B | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV61175983; called by muse, mutect2, varscan2
- ZNF407 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1364123390; called by muse, mutect2, varscan2
- ZNF462 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 204/594 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs762979271; called by muse, mutect2, varscan2
- ZNF560 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 194/336 reads (58%) | catalogued as rs1436319830; called by muse, mutect2, varscan2
- ZNF563 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs757126632; called by muse, mutect2, varscan2
- ZNF574 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 257/417 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs754746224, COSV55907858; called by muse, mutect2, varscan2
- ZNF607 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 135/216 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs752093789; called by muse, mutect2, varscan2
- ZNF608 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 157/385 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV60436025, COSV60439267; called by muse, mutect2, varscan2
- ZNF609 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 170/354 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV100441112; called by muse, mutect2, varscan2
- ZNF627 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 96/312 reads (31%) | catalogued as rs764121504, COSV63141922, COSV63142100; called by muse, mutect2, varscan2
- ZNF667 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 232/394 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52636991; called by muse, mutect2, varscan2
- ZNF697 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 129/414 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.727); catalogued as rs1416510395; called by muse, mutect2, varscan2
- ZNF729 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs763910391; called by muse, mutect2, varscan2
- ZNF730 | c.455_456del p.K152Sfs*4 | Frame Shift Del (DEL) | VAF 67/207 reads (32%) | catalogued as rs1568318866; called by mutect2, pindel, varscan2
- ZNF768 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 96/346 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs922005740; called by muse, mutect2, varscan2
- ZNF783 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 212/353 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1013924997; called by muse, mutect2, varscan2
- ZNF862 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 146/454 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs867798028; called by muse, mutect2, varscan2
- ZNF862 | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 149/451 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776850592; called by muse, mutect2, varscan2
- ZSWIM8 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 256/517 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1319034497; called by muse, mutect2, varscan2
- ABCA13 | c.5836G>A p.G1946S | Missense Mutation (SNP) | VAF 182/360 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ABCA13 | c.5837G>A p.G1946D | Missense Mutation (SNP) | VAF 182/358 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ABCA13 | c.9847C>T p.P3283S | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ABCA2 | c.1120G>A p.A374T (on ENST00000614293; = p.A344T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 1037/1039 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA4 | c.5387C>G p.S1796C | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ABCA7 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 268/433 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ABCC11 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 69/196 reads (35%) | called by muse, mutect2, varscan2
- ABCG5 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCG5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABHD5 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- AC024598.1 | c.1088G>A p.W363* | Nonsense Mutation (SNP) | VAF 186/397 reads (47%) | called by muse, mutect2, varscan2
- AC113554.1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 198/403 reads (49%) | called by muse, mutect2
- ACAD10 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 209/443 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ACAN | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 196/424 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACOT11 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 144/209 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOT11 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 168/277 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS12 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 88/532 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS6 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTSL2 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 704/705 reads (100%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2852C>T p.S951F | Missense Mutation (SNP) | VAF 75/482 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADARB2 | c.1623G>C p.W541C | Missense Mutation (SNP) | VAF 293/528 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGB | c.3180G>A p.K1060= | Splice Region (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- ADH1A | c.964+1G>A p.X322_splice | Splice Site (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- ADRB1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 156/643 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- AGAP2 | c.2476C>T p.P826S (on ENST00000547588 / NM_001122772.2; = p.P490S on NM_014770.4) | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- AGAP5 | c.566A>C p.E189A | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AGBL1 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 150/308 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AHNAK | c.13619C>T p.S4540F | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- AHRR | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 516/768 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AK7 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AKIP1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AL592490.1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 569/875 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ALDH1A1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 120/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH1B1 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ALDOB | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 302/490 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ALG6 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 107/182 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALKBH5 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 239/556 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALKBH8 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 110/460 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- AMBN | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 173/255 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AMPH | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 229/390 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.8761G>A p.D2921N | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ANKDD1B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKS1B | c.3080G>A p.G1027E (on ENST00000547776 / NM_152788.4; = p.G193E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ANO1 | c.2616G>A p.W872* | Nonsense Mutation (SNP) | VAF 167/356 reads (47%) | called by muse, mutect2, varscan2
- ANO3 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- AOC3 | c.2024T>G p.V675G | Missense Mutation (SNP) | VAF 124/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP1B1 | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 188/271 reads (69%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AP3B1 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- APOB | c.7531A>G p.K2511E | Missense Mutation (SNP) | VAF 229/378 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- APOH | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 192/369 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- APOL1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGAP24 | c.1756G>A p.G586R (on ENST00000395184 / NM_001025616.3; = p.G493R on NM_031305.3) | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ARHGAP45 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 323/483 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARHGEF11 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 109/347 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ARMC5 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 249/618 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ARMT1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 113/205 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ASAP2 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 152/228 reads (67%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASH1L | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ASIC2 | c.869_872delinsTA p.R290Lfs*18 | Frame Shift Del (DEL) | VAF 119/310 reads (38%) | called by pindel, varscan2*
- ASPA | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATG2B | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 77/353 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
1,584 further variants in this file (762 protein-altering or splice-affecting, 722 silent, 100 other) are not listed here.
